Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A1Q8, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A1Q8-06A (Metastatic).

105-0-3
Melanoma, NOS 8720/3
Site: lymph node, NOS C77.9
3/15/11 JW

DIAGNOSIS

(A) RIGHT AXILLARY CONTENTS:

METASTATIC MALIGNANT MELANOMA IN FIVE OF TWENTY-THREE LYMPH NODES

**LARGEST TUMOR DEPOSIT MEASURES 18.0 X 11.0 MM.
EXTRACAPSULAR EXTENSION IDENTIFIED.**

(B) RIGHT POSTERIOR SHOULDER MASS, SKIN ELLIPSE:

Skin and soft tissue resection with healing wound and follicular cyst infundibular type, excision.
Melanoma not identified. Margins have been evaluated.

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) RIGHT AXILLARY CONTENTS - A portion of adipose tissue measuring 46.0 x 36.0 x 16.0 cm with attached skin ellipse (19.0 x 2.0 cm).

A linear scar along the length of the skin ellipse there is an underlying biopsy site measuring 3.5 x 3.5 x 1.9 cm with associated fat necrosis. Twenty-five potential lymph nodes are grossly identified, four of them grossly appear positive, with the largest tumor nodule being 0.9 cm in greatest dimension grossly.

SECTION CODE: A1, three lymph nodes; A2-A5, one fatty node serially sectioned; A6, one lymph node bisected; A7, one lymph node bisected; A8, one lymph node; A9, one lymph node bisected; A10-A13, grossly suspicious lymph nodes for positive tumor in each cassette; A14, A15 one lymph node bisected; A16, A17 one lymph node bisected; A18, A19 one lymph node bisected; A20, four lymph nodes; A21, A22 one lymph node each; A23-A26, one lymph node bisected in each cassette; A27, biopsy site; A28, skin with scar; A29, specimen deep margin (shave);

(B) RIGHT POSTERIOR SHOULDER MASS - The specimen consists of an elliptical skin excision (2.8 x 1.5 x 1.5 cm) with two stitches.

The epidermis is grossly unremarkable with no hyperpigmentation. There are focal white and friable areas in the middle of the specimen measuring (0.6 x 0.6 x 0.5 cm).

Superior resection margin is inked blue and the inferior resection margin is inked orange.

The specimen is serially sectioned and entirely submitted in cassettes B1-B7 from lateral to medial.

CLINICAL HISTORY

History of metastatic melanoma, right axilla mass, right shoulder.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by Medicine. These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."
Released by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file b6fe6209-60ca-4491-b28f-6545542d00e3 (TCGA-D3-A1Q8.F0634F7F-0FFB-4317-A808-00BB4F612B3E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).